Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A27R, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A27R-01A (Primary Tumor).

[page 1 of 2]
100-0-3
carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9

page 1 / 2

original

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: **Total organ resection – right breast with axillary tissues**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: **up to 8 working days**

Clinical diagnosis: **Cancer of the right breast**

HPA Discrepancy		X

Examination performed on

Macroscopic description:

Right breast sized 14.4 x 11.2 x 4.2 cm removed along with axillary tissues sized 8 x 5 x 2 cm and a skin flap of 12,2 x 8.8 cm. Weight 330 g.

Tumour sized 3.2 x 2.3 x 2.6 cm found on the boundary of upper quadrants, located 1.6 cm from the upper boundary, 0.5 cm from the base and 1.2 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum - NHG3 (3 + 3 + 3 / 20 mitoses/10 HPF - visual area: 0.55mm).

Numerous foci of carcinoma ductale in situ DCIS found within the tumour (solid type with high nuclear atypia and comedo necrosis with calcinations, 20% of the tumour volume).

Invasio carcinomatosa vasorum massiva.

Emboliae carcinomatosa mamillae.

Glandular texture showing parenchyma of normal structure.

In situ lesions removed by 0.1 cm from the base

AXILLARY LYMPH NODES:

Metastases carcinomatosa in lymphonodis (No XI/XI).

Infiltratio telae perinodalis.

Emboliae carcinomatosa vasorum.

Test result:

Incl. Examination

Carcinoma ductale invasivum mammae dextrae. Invasive ductal carcinoma of the right breast

Metastases carcinomatosa in lymphonodis axillae. Cancer metastases in axillary lymph nodes. (No XI/XI) (NHG3, pT2, pN3a).

Invasio carcinomatosa vasorum massiva. Massive vascular invasion.

Compliance validated by:

Examination performed on

[page 2 of 2]
Examination No.:

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in 10-75% neoplastic cell nuclei.

HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody. Score=2+, FISH

verification recommended.

dr

Compliance validated by

Source: NCI Genomic Data Commons file 66209c3d-095b-4ab6-ae7e-ead438c6f619 (TCGA-D8-A27R.5E997487-9A03-4723-B1E6-FA0B557D8FDF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).